Somatic mutation profile of tumor specimen MP2PRT-PAVJXI-TMP1-A (aliquot MP2PRT-PAVJXI-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVJXI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,756 days).
Specimen MP2PRT-PAVJXI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3da7ef81-077f-4c63-a813-2b07cba8e597.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJXI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJXI-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b52f8a9b-a00f-47b1-b8fb-38a1ee7fbadc

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Ins 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 113/284 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.1355G>A p.C452Y | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65387192; called by muse, mutect2
- GAL3ST3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 259/537 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV61748834, COSV61749286; called by muse, mutect2, varscan2
- TENM4 | c.4404G>T p.E1468D | Missense Mutation (SNP) | VAF 149/360 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV53614857; called by muse, mutect2, varscan2
- TRMT1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV52833859; called by muse, mutect2, varscan2
- TTN | c.3020C>T p.A1007V (on ENST00000591111; = p.A961V on NM_003319.4) | Missense Mutation (SNP) | VAF 189/393 reads (48%) | PolyPhen probably damaging (0.997); catalogued as rs749564348, COSV60172082, COSV60315591; called by muse, mutect2, varscan2
- TVP23C | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 189/569 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV56669433; called by muse, mutect2, varscan2
- ZNF735 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs773098060, COSV70034667; called by muse, varscan2
- ZSCAN10 | c.1646G>A p.R549Q (on ENST00000252463; = p.R604Q on NM_032805.3) | Missense Mutation (SNP) | VAF 204/442 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1000846730, COSV52968266; called by muse, mutect2, varscan2
- AJM1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 84/779 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARMIL3 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- DOP1B | c.6517_6518insTC p.Y2173Ffs*21 | Frame Shift Ins (INS) | VAF 99/430 reads (23%) | called by mutect2, pindel, varscan2
- ERC2 | c.1720A>T p.T574S | Missense Mutation (SNP) | VAF 157/294 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- USP9X | c.6078_6079insAACCT p.P2027Nfs*18 | Frame Shift Ins (INS) | VAF 40/168 reads (24%) | called by mutect2, pindel, varscan2
- DACT2 | c.840C>T p.H280= | Silent (SNP) | VAF 84/598 reads (14%) | catalogued as rs569420736; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 TCACAGT>GA | Silent (DEL) | VAF 81/153 reads (53%) | called by pindel, varscan2*
- OR5M3 | c.315T>A p.L105= | Silent (SNP) | VAF 84/125 reads (67%) | called by muse, mutect2, varscan2
- TENM4 | c.4581C>T p.D1527= | Silent (SNP) | VAF 178/406 reads (44%) | catalogued as rs374134408; called by muse, mutect2, varscan2
- FLT4 | c.*502G>T | 3'UTR (SNP) | VAF 133/310 reads (43%) | catalogued as rs563268325; called by muse, mutect2, varscan2
- IER3 | c.211-10C>T | Intron (SNP) | VAF 281/903 reads (31%) | called by muse, mutect2, varscan2
